Somatic mutation profile of tumor specimen TCGA-BS-A0WQ-01A (aliquot TCGA-BS-A0WQ-01A-21D-A10G-09) from TCGA case TCGA-BS-A0WQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 55.1 years (20,131 days).
Specimen TCGA-BS-A0WQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f225295-3a59-4199-a41a-63ffbde0d0e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0WQ-10A (Blood Derived Normal), aliquot TCGA-BS-A0WQ-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8047fa7-a48c-46b2-a962-ae9ac4c0823c

The open-access MAF lists 55 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 34, Silent 12, Frame Shift Ins 4, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.3398C>T p.T1133M | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064793083, CM1513880, COSV71110425; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 36/100 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 100/214 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.545dup p.L182Ffs*8 | Frame Shift Ins (INS) | VAF 220/435 reads (51%) | catalogued as rs878853941; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADGRD1 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55445358; called by muse, mutect2, varscan2
- ALDH1A3 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV104395673, COSV60901743; called by muse, mutect2, varscan2
- ALG13 | c.2686G>A p.G896S | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs972892187, COSV52638954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AVPR2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782054894, CM1210555, COSV61686208; called by muse, mutect2, varscan2
- CDH4 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs776268387, COSV64642966; called by muse, mutect2, varscan2
- DDX24 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs1191042383, COSV58212465; called by muse, mutect2, varscan2
- DLC1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.425); catalogued as rs368389913, COSV99363842; called by muse, mutect2, varscan2
- EIF3B | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV62803372, COSV62805029; called by muse, mutect2, varscan2
- EPHA5 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778795902, COSV56645189; called by muse, mutect2, varscan2
- FAM133A | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs762182826, COSV59075317; called by muse, mutect2, varscan2
- GOLGA6L22 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.225); catalogued as rs1459454497; called by muse, mutect2, varscan2
- GPRIN1 | c.582T>A p.D194E | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV56138692; called by muse, mutect2, varscan2
- KIF18B | c.2431G>T p.A811S (on ENST00000593135 / NM_001265577.2; = p.A823S on NM_001264573.2) | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.275); catalogued as COSV59273004; called by muse, mutect2, varscan2
- LRRC4B | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as rs764615082, COSV65350061; called by muse, mutect2, varscan2
- MMS22L | c.2149C>A p.L717M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51521108, COSV51524882; called by muse, mutect2, varscan2
- MPP2 | c.527G>T p.G176V (on ENST00000461854 / NM_001278372.2; = p.G152V on NM_005374.5) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV52235795; called by muse, mutect2, varscan2
- MYL5 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as rs765244059, COSV59140296; called by muse, mutect2, varscan2
- NCKAP5 | c.3167C>G p.T1056S | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV58438445, COSV58443806; called by muse, mutect2, varscan2
- NID1 | c.1241G>A p.C414Y | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51620173; called by muse, mutect2, varscan2
- PCDH9 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 93/172 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); catalogued as COSV60550345; called by muse, mutect2, varscan2
- PDHX | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1291802569, COSV53506842; called by muse, mutect2, varscan2
- PKHD1 | c.8935C>T p.R2979* | Nonsense Mutation (SNP) | VAF 53/128 reads (41%) | catalogued as rs765020336, CM100564, COSV61875321; called by muse, mutect2, varscan2
- PLXNB2 | c.2668T>G p.F890V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63781690; called by muse, mutect2, varscan2
- PXDNL | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373683927, COSV62484789; called by muse, mutect2, varscan2
- RBM27 | c.2280T>A p.S760R | Missense Mutation (SNP) | VAF 93/195 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV54589843; called by muse, mutect2, varscan2
- RDH5 | c.718dup p.A240Gfs*19 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | catalogued as rs753378940; called by mutect2, varscan2
- SMC1A | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59129240; called by muse, mutect2, varscan2
- TAB3 | c.569A>T p.Y190F | Missense Mutation (SNP) | VAF 126/246 reads (51%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.998); catalogued as COSV55836938; called by muse, mutect2, varscan2
- TBC1D4 | c.3304G>A p.A1102T | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV66489220; called by muse, mutect2, varscan2
- TNNT1 | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV52571792, COSV99402902; called by muse, mutect2, varscan2
- TTC37 | c.4442C>T p.P1481L | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs748026052, COSV62453239, COSV62454781; called by muse, mutect2, varscan2
- USP26 | c.1044dup p.K349* | Frame Shift Ins (INS) | VAF 12/27 reads (44%) | catalogued as rs772870708; called by mutect2, varscan2
- WAPL | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 96/325 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV53935110; called by muse, mutect2, varscan2
- WARS1 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.102); catalogued as rs1400283241, COSV59925553; called by muse, mutect2, varscan2
- ZNF654 | c.2224C>T p.Q742* | Nonsense Mutation (SNP) | VAF 70/134 reads (52%) | catalogued as COSV58805852; called by muse, mutect2, varscan2
- ARHGAP35 | c.1334del p.F445Sfs*2 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- ASCC2 | c.132del p.D46Tfs*6 | Frame Shift Del (DEL) | VAF 36/68 reads (53%) | called by mutect2, varscan2
- KIAA1217 | c.369dup p.L124Tfs*12 | Frame Shift Ins (INS) | VAF 42/143 reads (29%) | called by mutect2, pindel, varscan2
- NBEAL2 | c.3175_3177del p.K1059del | In Frame Del (DEL) | VAF 21/52 reads (40%) | called by pindel, varscan2
- ACSS1 | c.2001C>T p.D667= | Silent (SNP) | VAF 58/98 reads (59%) | catalogued as rs772987058, COSV60220247; called by muse, mutect2, varscan2
- ANKIB1 | c.894C>G p.A298= | Silent (SNP) | VAF 66/153 reads (43%) | catalogued as COSV56061425; called by muse, mutect2, varscan2
- BCR | c.3505C>T p.L1169= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs1301451798, COSV59926214, COSV59931082; called by muse, mutect2, varscan2
- BLZF1 | c.129G>A p.K43= | Silent (SNP) | VAF 69/134 reads (51%) | catalogued as COSV61393552; called by muse, mutect2, varscan2
- CFAP46 | c.8134C>T p.L2712= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV54152386; called by muse, mutect2
- CLEC4M | c.912C>T p.V304= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs749659860, COSV50218974; called by muse, mutect2, varscan2
- LPCAT1 | c.396C>T p.L132= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs149874412; called by muse, mutect2, varscan2
- MTNR1B | c.735C>T p.S245= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs376871685; called by muse, mutect2, varscan2
- PCDHA12 | c.288C>T p.C96= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as rs781811926, COSV56501287; called by muse, mutect2, varscan2
- RIN3 | c.1122G>A p.P374= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs370750024; called by muse, varscan2
- RP1 | c.669A>G p.G223= | Silent (SNP) | VAF 96/162 reads (59%) | called by muse, mutect2, varscan2
- SCPEP1 | c.1263T>C p.L421= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as COSV51854288; called by muse, mutect2, varscan2
